ALCHEMIST case ALCH-AEP6 — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/3437ed29-ff16-4666-a095-20f716db2bf3

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 57.8 years (21,101 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AEP6-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AEP6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AEP6-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 24; Percent tumor nuclei: 62; Percent normal cells: 26; Percent necrosis: 35; Percent stromal cells: 15; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
